Somatic mutation profile of tumor specimen 0DM1KB from CCDI case PBBUPW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Aggressive fibromatosis; Tissue or organ of origin: Connective, subcutaneous and other soft tissues, NOS; Age at diagnosis: 12.8 years (4,671 days).
Specimen 0DM1KB: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 855e3fc8-cac2-49bd-8959-d16f0585bac9.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JA (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93d53f7e-0624-48cc-b6fe-cc0964c86add

The open-access MAF lists 2 somatic variants for this specimen: 1 protein-altering or splice-affecting, 1 silent.
By variant classification: Silent 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA10 | c.583A>T p.M195L | Missense Mutation (SNP) | VAF 57/610 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2
- SRPK2 | c.273C>T p.H91= | Silent (SNP) | VAF 70/1201 reads (6%) | called by muse, mutect2
